Gene-level copy-number profile of tumor specimen TCGA-ER-A19T-06A from TCGA case TCGA-ER-A19T, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acral lentiginous melanoma, malignant; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.5 years (18,802 days).
Specimen TCGA-ER-A19T-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a9e949e0-01ff-4547-9666-edcd44aac9fd.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 405 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5a41743-37f7-4761-94e5-dc4046720251

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 796; copy number 2: 20,967; copy number 3: 15,007; copy number 4: 16,648; copy number 5: 2,626; copy number 6: 1,330; copy number 7: 1,429; copy number 8: 130; copy number 9: 118; copy number 10: 123; copy number 11: 14; copy number 12: 20; copy number 13: 1; copy number 14: 63; copy number 15: 52; copy number 16: 11; copy number 17: 8; copy number 18: 60; copy number 19: 25; copy number 20: 67; copy number 22: 16; copy number 23: 12; copy number 24: 5; copy number 26: 23; copy number 27: 8; copy number 29: 10; copy number 31: 19; copy number 32: 1; copy number 33: 2; copy number 37: 4; copy number 40: 45; copy number 44: 21; copy number 49: 1; copy number 52: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19T-06A-11D-A192-01): tumor purity 0.73, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,685,439–14,472,407, 23 genes: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,257 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,630,767–8,026,309, 90 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:27,229,106–29,905,357, 99 genes, copy number 5 (broad region; genes not listed).
- chr1:30,409,560–71,489,976, 990 genes, copy number 6–10 (broad region; genes not listed).
- chr1:119,596,167–121,580,524, 53 genes, copy number 6: GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr2:37,923,187–39,717,963, 44 genes, copy number 5: RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12, GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1, SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA, CDKL4, MAP4K3, AC007684.1, AC007684.2, MAP4K3-DT, TMEM178A.
- chr4:27,917,753–32,353,220, 31 genes, copy number 5: AC007106.2, AC007106.1, AC093791.2, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353.
- chr5:321,759–892,801, 20 genes, copy number 5 (within-gene range 2–5): AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9.
- chr6:53,090,961–53,418,737, 18 genes, copy number 6: RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3.
- chr7:68,149,548–68,319,676, 3 genes, copy number 5 (within-gene range 4–5): AC093655.1, AC093655.2, MTND4P3.
- chr7:79,030,240–86,217,733, 56 genes, copy number 5: RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr7:129,756,266–131,497,694, 55 genes, copy number 5: RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2.
- chr7:139,777,051–141,480,380, 34 genes, copy number 6: TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P, TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2.
- chr8:43,672,823–49,229,174, 66 genes, copy number 9 (within-gene range 9–28) (broad region; genes not listed).
- chr8:53,162,339–53,484,067, 6 genes, copy number 5–29 (within-gene range 3–29): AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2.
- chr8:54,042,989–54,247,906, 8 genes, copy number 17: AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1.
- chr8:54,381,698–145,066,685, 1,408 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr9:34,521,043–36,677,683, 104 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr10:119,726,042–119,958,592, 7 genes, copy number 5 (within-gene range 2–5): INPP5F, RN7SL846P, PHACTR2P1, AL133461.1, MCMBP, SEC23IP, MIR4682.
- chr11:25,588,475–25,782,017, 3 genes, copy number 5 (within-gene range 4–5): RPL36AP40, AC100770.1, LINC02699.
- chr11:67,483,026–71,997,597, 153 genes, copy number 5–20 (within-gene range 4–25) (broad region; genes not listed).
- chr11:73,510,658–79,441,030, 169 genes, copy number 5–49 (within-gene range 2–77) (broad region; genes not listed).
- chr11:86,374,736–89,301,477, 53 genes, copy number 31–52: CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3, AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P, TYR, CBX3P7, AP000720.1, AP000720.2.
- chr11:101,129,077–101,872,562, 5 genes, copy number 24–31 (within-gene range 4–31): PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1.
- chr13:18,467,172–20,196,005, 66 genes, copy number 5 (broad region; genes not listed).
- chr13:33,800,138–39,791,665, 75 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:75,902,136–77,935,014, 65 genes, copy number 5 (broad region; genes not listed).
- chr14:104,085,686–106,875,071, 258 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–23,447,243, 169 genes, copy number 5 (broad region; genes not listed).
- chr15:46,827,526–90,102,477, 1,079 genes, copy number 5–26 (within-gene range 5–30) (broad region; genes not listed).
- chr15:98,954,149–99,105,824, 3 genes, copy number 5: AC036108.1, PGPEP1L, LUNAR1.
- chr17:69,961,568–73,092,712, 33 genes, copy number 5 (within-gene range 4–5): LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1.
- chr17:75,370,947–77,728,559, 119 genes, copy number 8 (broad region; genes not listed).
- chr17:80,351,828–81,900,991, 82 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr18:11,758,977–11,929,476, 9 genes, copy number 5 (within-gene range 3–5): AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3.
- chr18:12,031,178–12,040,300, 2 genes, copy number 5: AP001542.3, AP001542.1.
- chr18:39,655,645–40,247,367, 10 genes, copy number 18: AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1.
- chr18:41,955,234–62,980,433, 330 genes, copy number 5–16 (within-gene range 2–16) (broad region; genes not listed).
- chr18:66,946,116–73,745,232, 75 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr19:15,613,247–15,630,639, 2 genes, copy number 5 (within-gene range 3–5): AC093072.1, CYP4F8.
- chr22:38,219,291–50,801,309, 392 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 796. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
